Somatic mutation profile of tumor specimen 0DXLTM from CCDI case PBCPZX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.8 years (3,578 days).
Specimen 0DXLTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3487989e-c41f-4908-a201-f932b0ac3f0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXLT0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8a52b2b-ec34-4848-8b86-54f35113c293

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA3 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64798635; called by muse, mutect2, varscan2
- KRT8 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 91/435 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs376270554, COSV53176339; called by muse, varscan2
- LARP7 | c.1354G>C p.V452L | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs202109173; called by muse, mutect2, varscan2
- LMBRD2 | c.369-2A>G p.X123_splice | Splice Site (SNP) | VAF 68/216 reads (31%) | catalogued as COSV56952830; called by muse, mutect2, varscan2
- PANX2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 111/472 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50304464; called by muse, mutect2, varscan2
- SEC16A | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs776749643; called by muse, mutect2, varscan2
- SLC4A10 | c.1433G>A p.R478Q (on ENST00000446997 / NM_001354461.2; = p.R448Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs866130595, COSV55764248; called by muse, mutect2, varscan2
- TPBG | c.519T>G p.S173R | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV63883085; called by muse, mutect2, varscan2
- ZSWIM4 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs765615457; called by muse, mutect2, varscan2
- ADGRG4 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HSPA6 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 32/674 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- COX18 | c.687C>T p.I229= | Silent (SNP) | VAF 91/478 reads (19%) | called by muse, mutect2, varscan2
- CSMD2 | c.2547G>A p.S849= | Silent (SNP) | VAF 24/524 reads (5%) | catalogued as rs778345880, COSV99587516; called by muse, mutect2
- CYBA | c.471G>A p.P157= | Silent (SNP) | VAF 90/277 reads (32%) | catalogued as rs992691010, COSV54918591, COSV99733209; called by muse, mutect2, varscan2
- FRK | c.693C>T p.R231= | Silent (SNP) | VAF 84/346 reads (24%) | catalogued as rs1354728916; called by muse, mutect2, varscan2
- PSKH2 | c.1137G>A p.S379= | Silent (SNP) | VAF 56/348 reads (16%) | catalogued as rs774775549, COSV52612333; called by mutect2, varscan2
- PTPRE | c.390C>T p.D130= | Silent (SNP) | VAF 53/262 reads (20%) | called by muse, mutect2, varscan2
- SCRN3 | c.144G>T p.L48= | Silent (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- SPDYE1 | c.952-14G>A | Intron (SNP) | VAF 15/137 reads (11%) | catalogued as rs1163442459; called by muse, mutect2, varscan2
- ZNF780A | c.*1481C>A | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
